Surgical pathology report (de-identified scan), TCGA case TCGA-P4-A5E6, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site  MD Anderson Cancer Center, specimen TCGA-P4-A5E6-01A (Primary Tumor).

[page 1 of 2]
Department of Pathology

Tissue Source Site (TSS) #:

Pathology Accession No:

Patient ID:

Normal Sample ID:

Pathology Report

***** MODIFIED REPORT - REVIEW ADDENDUM SECTION *****

COMMENT

This addendum report is issued to comment on the type of papillary renal cell carcinoma, as it was not mentioned in the original report. There is no other change in diagnosis.

After review of the H&E slides, this tumor is designated as type 2 papillary renal cell carcinoma.

DIAGNOSIS

(A) LEFT 12TH RIB:

Segment of rib, for gross inspection only.

(B) LEFT KIDNEY AND ADRENAL:

PAPILLARY RENAL CELL CARCINOMA, FUHRMAN'S NUCLEAR GRADE 3.

TUMOR CONFINED TO THE KIDNEY.

TUMOR MEASURES 6.5 CM IN MAXIMUM DIMENSION.

Vascular ureteral and soft tissue margins of resection free of tumor.

Multiple renal cortical adenomas (0.3 cm in maximum dimension).

Multiple renal cortical (simple) cysts (5.0 cm in maximum dimension).

Adrenal cortical hyperplasia.

(C) HILAR LYMPH NODES:

METASTATIC PAPILLARY RENAL CELL CARCINOMA IN ONE OF THREE LYMPH NODES. (SEE COMMENT)

COMMENT

The metastatic focus in one lymph node consists of a few clusters of neoplastic cells in the subcapsular sinus and measures less than 0.1 cm in maximum dimension. Multiple additional deeper sections were examined.

GROSS DESCRIPTION

(A) LEFT 12TH RIB, GROSS ONLY - A tan-pink linear fragment of bone (6.0 x 1.5 x 0.6 cm). The specimen is submitted as gross only.

(B) LEFT KIDNEY AND ADRENAL - A left radical nephrectomy (24.0 x 10.0 x 7.0 cm) consisting of a kidney (14.0 x 0.5 x 7.0 x 6.5 cm) and adrenal gland (8.0 x 3.0 x 2.5 cm).

Within the mid portion of the kidney is a well circumscribed soft friable mass (6.5 x 5.5 x 5.5 cm). The tumor pushes against the perirenal adipose tissue but does not appear to invade it, the tumor also pushes against the renal pelvis but does not appear to invade. The tumor does not appear to invade the renal vein.

The uninvolved kidney parenchyma is remarkable for several cysts ranging size from 0.5 to 5.0 cm in greatest diameter. They are mainly located in the cortex. Also present are approximately seven yellow nodules, all of which measure (<0.3 cm in greatest dimension). The adrenal gland is remarkable for a large nodule and diffuse enlargement.

A portion of tumor and kidney is submitted to the tissue bank.

SECTION CODE: B1, renal artery vein and ureter margin; B2, tumor in relation to renal pelvis; B3, tumor in relation to renal pelvis; B4, tumor in relation to renal pelvis and adjacent kidney; B5, tumor in

ILD-0-3
Carcinoma, papillary
renal cell 826013
Site @ Kidney NOS
C64.9
gnd 11/01/13

Criteria	W 12/31/12	Yes	No
Case is Circled			

[page 2 of 2]
Department of Pathology

Tissue Source Site (TSS) #:

Pathology Accession No:

Patient ID

Normal Sample ID:

Tumor Sample ID:

relation to the kidney; B6, tumor in relation to perirenal adipose tissue and renal capsule; B7-B8, representative sections of tumor; B9-B12, representative sections of yellow nodules throughout parenchyma; B13-B17, representative sections of cyst; B17-B19, representative sections of adrenal gland.

(C) HILAR LYMPH NODES - A tan-pink irregular portion of adipose tissue (5.5 x 1.5 x 1.0 cm). The specimen is serially sectioned and multiple lymph nodes are identified ranging in size from 0.5 x 0.5 x 0.3 to 1.5 x 1.0 x 0.6 cm). The lymph nodes are submitted in toto.

SECTION CODE: C1, two lymph nodes; C2, one lymph node bisected.

CLINICAL HISTORY

Left renal mass.

SNOMED CODES

T-71000, M-Y7343, T-C4600, M-Y7346

Source: NCI Genomic Data Commons file ec192d14-9b98-445c-966c-350dc9f250d4 (TCGA-P4-A5E6.554C324B-C9C3-4936-B5E4-B3541A54364D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).